CPTAC case C3N-02188 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/96ddb2ea-c179-46d2-9676-4fa88dba1d93

Demographics
Sex at birth: male; Race: asian; Year of birth: 1958; Vital status: Dead; Days to death: 411 days (1.1 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 59.4 years (21,709 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 411 days (1.1 years); Progression or recurrence: yes; Days to recurrence: 260 days; Days to last follow up: 411 days (1.1 years).
   Pathology details: Greatest tumor dimension: 5.2 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 350 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 411 days (1.1 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 260 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 70 kg; Height: 180 cm; BMI: 21.6.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (10 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-02188-01, C3N-02188-02 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 150 mg.
- Sample C3N-02188-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 150 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02188-23: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 2.
- Samples C3N-02188-31, C3N-02188-32, C3N-02188-72, C3N-02188-73, C3N-02188-74, C3N-02188-75 (6 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02188-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
